Somatic mutation profile of tumor specimen TCGA-EJ-5515-01A (aliquot TCGA-EJ-5515-01A-01D-1576-08) from TCGA case TCGA-EJ-5515, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.5 years (22,097 days).
Specimen TCGA-EJ-5515-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a881a1d-c910-44ff-9623-768ecce04956.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5515-10A (Blood Derived Normal), aliquot TCGA-EJ-5515-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20625641-ee4c-44d4-8fbc-933ba2443c47

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF5B | c.1427T>C p.M476T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1411335084, COSV56812550, COSV56813270; called by muse, mutect2, varscan2
- HGF | c.925C>A p.Q309K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.991); catalogued as COSV55948429; called by muse, mutect2
- KCNG1 | c.1255G>T p.V419F | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100857183, COSV65368902; called by muse, mutect2
- OR13C2 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV73377690; called by muse, mutect2
- RC3H2 | c.3259A>G p.S1087G | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV61799670; called by muse, mutect2
- RNF20 | c.1500A>T p.K500N | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV66660939; called by muse, mutect2
- ZNF813 | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV104433511, COSV67176368; called by muse, mutect2
- CD248 | c.1743G>A p.Q581= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV60936328; called by muse, mutect2
